Gene-level copy-number profile of tumor specimen HCM-SANG-0272-C20-01A-01D-A80T-32 from HCMI case HCM-SANG-0272-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0272-C20-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 804d919f-a500-442b-a6e3-9938dd4db490.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0272-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/8b6467a4-b484-4234-8684-ae4cfafa80e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 12,395; copy number 2: 39,541; copy number 3: 6,338; copy number 4: 97; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,691,262–49,691,523, 1 gene (within-gene range 0–1): AL390023.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr14:83,048,579–84,177,088, 7 genes: RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, MTND4P33, MTND5P35, MTCYBP27.
- chr15:34,489,002–34,588,503, 6 genes: HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.
- chr15:77,041,404–77,420,144, 7 genes (within-gene range 0–1): TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.

Autosomal genes at a single copy (total copy number 1): 10,967. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
